Somatic mutation profile of tumor specimen TCGA-E8-A433-01A (aliquot TCGA-E8-A433-01A-11D-A23M-08) from TCGA case TCGA-E8-A433, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 25.0 years (9,145 days).
Specimen TCGA-E8-A433-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb44b89f-6cef-4b57-a0df-f81d8e624566.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A433-10A (Blood Derived Normal), aliquot TCGA-E8-A433-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/317f4acb-4c7e-4212-a5b5-9a1cb655db78

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAM12 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs762714097, COSV64106750, COSV64116776; called by muse, mutect2, varscan2
- LYN | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV70205682; called by muse, mutect2, varscan2
- MMP13 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52824036; called by muse, mutect2, varscan2
- PCDHA6 | c.1306T>A p.W436R | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); catalogued as COSV65344123; called by muse, mutect2, varscan2
- SF3B1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as rs190499887, COSV100133596, COSV59214030; called by muse, mutect2, varscan2
- SIAE | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV55014266; called by muse, mutect2, varscan2
- SNRNP70 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1568424180, COSV55505756; called by muse, mutect2, varscan2
- LRRK2 | c.4176del p.W1393Gfs*17 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- RARA | c.773_774insA p.T259Hfs*65 | Frame Shift Ins (INS) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- ASAP2 | c.597C>T p.C199= | Silent (SNP) | VAF 60/213 reads (28%) | catalogued as rs772270223, COSV55631673; called by muse, mutect2, varscan2
